Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACQA, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACQA-TTP1-A (Primary Tumor).

[page 1 of 2]
Sample sent as:

1. Intra fissure pulmonary nodule, extemporaneous examination
2. right upper lobe pulmonary nodule, extemporaneous examination

Macroscopic report:

1. fragment of pulmonary parenchyma of cm 0.7x0.5x0.3
2. two fragments of lung parenchyma of cm 0.5x0.3x0.3 and cm 1.2x0.2x0.2

Conclusions and diagnosis

1. negative for malignancy
2. adenocarcinoma (see note)

CDDP-YP-ACQA-01-PR

Note: interim response reported by telephone being extemporaneous examination to the
. Following the final report of fixed included material

Clinical questions and diagnostic data

patients with right pulmonary neoplasm

Sample sent as:

1. Intra fissure pulmonary nodule, surgical biopsy
2. Right upper lobe pulmonary nodule, surgical biopsy
3. Lymph node n10, surgical biopsy
4. Lymph node n11, surgical biopsy
5. Right upper lobe, surgical specimen
6. Lymph nodes of the Baret's space, surgical biopsy
7. Lymph node n4, surgical biopsy
8. Lymph node n4, surgical biopsy
9. Lymph node n4, surgical biopsy
10. Lymph node n7, surgical biopsy

ICB-0-3

adenocarcinoma, NOS 814013
Site: (A) lung, upper lobe C34.1

ICB-10

C 34.11

lw
12/14/12

Macroscopic report:

1. Fragment of pulmonary parenchyma of cm 0.7x0.5x0.3.
2. Two fragments of lung parenchyma, respectively of cm 0.5x0.3x0.3 and cm 1.2x0.2x0.2.
3. Two fragments of anthracotic tissue, the greatest of cm 1
4. One frustule of anthracotic tissue of cm 0.8
5. Lung lobe of cm 14x11x3.5, held back by metal sutures, at the level of the pleural surface, on the rib side, see area already incise and retained by stitches.
In such a place in the underlying lung parenchyma it's present a whitish gray tissue vaguely nodular, with irregular margins, of cm 0.7 of major axis. Situated about cm 1 from the pleural surface and distant of the hilar structures.
From the hilum region isolate 4 anthracotic lymph nodes, the greater one of cm 1.5
6. One frustule of gray-anthracotic tissue of cm 0.5

[page 2 of 2]
7. Two lymph nodes, both of cm 0.5
8. One lymph node of cm 0.3
9. One frustule of cm 0.3
10. Two lymph node, the greatest of cm 0.6.

Microscopic report:

1. Confirming what verbally expressed in the course of extemporaneous examination, the definitive histological sections after fixation and inclusion evidence, fragment of pulmonary parenchyma subpleural negative for malignancy.
2. Confirming what verbally expressed in the course of extemporaneous examination, histological sections after fixation and inclusion evidence epithelial malignant neoplastic process, with adenocarcinoma characters. It is made up of large size elements. frequently columnar with hyperchromic nucleus, irregular, markedly pleomorphic and nucleolar. The elements are arranged individually, in tubules, glands, sometimes in nests and aggregates more solid. Are detected mitosis, foci of necrosis and scattered mitosis. They are also present focal papillary aspects.
3. 6.7.8.10. The lymph nodes n10, Lymph nodes of the Barety's space, n4 and n7 are anthracotic and they are negative for neoplasia.
4. The biopsy sample refers to a small fragment of pulmonary parenchyma. No evidence of neoplasia
5. Histologically the lesion macroscopically described corresponds to epithelial malignant neoplastic process with adenocarcinoma characters. It consists of tubules, glands, nests and aggregates of atypical elements with vesicular nucleus, irregular, pleomorphic and nucleolar nucleus. Neoplastic proliferation infiltrating the lung parenchyma; they are detected mitosis. Foci of necrosis, stromal desmoplasia associated with necrosis. No evidence of invasion intra and / or peritumoral.
Non-neoplastic lung parenchyma has bronchitis of type respiratory. The four blocks hilar lymph nodes are anthracotic and negative for neoplasia. Negative for neoplasia the bronco section.
9. The biopsy sample consists of very minute frustule of adipose tissue and some vascular structures. No evidence of neoplasia.

Findings and histopathological diagnosis

1. Pulmonary parenchyma negative for malignancy
2. Moderately differentiated adenocarcinoma with foci of necrosis
3. 6.7.8.10. Anthracosis lymph node
4. 9. Negative for malignancy
5. Moderately differentiated adenocarcinoma infiltrating the lung parenchyma. Anthracosis hilar lymph node.
Bronco negative section to neoplasia

Source: NCI Genomic Data Commons file 3f1c306c-f270-402f-accf-85387b2399e8 (CDDP-ACQA-TTP1.7D65991E-736E-4EB7-972A-DF7A17120BF3.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).